Surgical pathology report (de-identified scan), TCGA case TCGA-3G-AB0Q, project TCGA-THYM (Thymoma), tissue source site MD Anderson Cancer Center, specimen TCGA-3G-AB0Q-01A (Primary Tumor).

[page 1 of 2]
Accession:
Specimen Date/Time:

DIAGNOSIS

- (A) THYMUS AND PERICARDIUM:
THYMOMA, SPINDLE CELL, INVASIVE.
Margin of resections, negative for tumor.
- (B) LUNG, RIGHT MIDDLE LOBE, WEDGE:
Fragments of lung parenchyma with focal ossification.

06CF ICD-O-3
Thymoma, type A, malignant 8581/3
path Thymoma spindle cell, malignant 8581/3
Site: Thymus 6579
J 6/15/14

GROSS DESCRIPTION

(A) THYMUS AND PERICARDIUM - A well circumscribed mass, 9.5 x 7.0 x 5.8 cm, fibroadipose tissue, 15.0 x 10.0 x 1.5 cm and one piece of pericardium, 9.0 x 5.0 cm. A resection margin inked black. The specimen is serially sliced. Cut surface reveal a well encapsulated white-tan lobular and nodular soft tumor. No necrosis and hemorrhage are identified in the tumor.

SECTION CODE: A1, A2, tumor and pericardium with resection margin of pericardium; A3, A4, tumor and closest resection margin of soft tissue; A5-A9, tumor and around soft tissue; A10, representative section of adipose tissue.

(B) RIGHT MIDDLE LOBE WEDGE - One pale tan wedge specimen (1.6 x 0.4 x 0.4 cm) with pale tan pleura with focal hemorrhage. The parenchymal resection margin is inked and specimen serially sectioned perpendicular to the parenchymal resection margin. One pale gray, firm nodule (0.2 x 0.2 x 0.2 cm) is identified, located at 0.4 cm from parenchymal resection margin and abutting the pleura. Specimen entirely submitted.

INK CODE: Blue - resection margin of parenchyma.

SECTION CODE: B1, nodule with adjacent tissue; B2, remainder of the specimen.

CLINICAL HISTORY

Thymoma

SNOMED CODES

T-D3300, M-85800

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

-----END OF REPORT-----

Pw TSS dx discrepancy form,
TCGA tumor is thymoma, type A

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name) _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Thymoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	A	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Histologic subtype was not done at initial pathologic diagnosis. Reviewing Pathologist has re-reviewed the case slide and provided the WHO subtype	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnosis.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 83d41853-c1d3-47b3-bc03-adda57707370 (TCGA-3G-AB0Q.76FF0EA8-C540-4F12-B44E-8F2DD900C34B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).